Somatic mutation profile of tumor specimen TCGA-AZ-6605-01A (aliquot TCGA-AZ-6605-01A-11D-1835-10) from TCGA case TCGA-AZ-6605, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.0 years (28,485 days).
Specimen TCGA-AZ-6605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8d60430-689e-4699-a87e-9d375b1edec5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6605-11A (Solid Tissue Normal), aliquot TCGA-AZ-6605-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54aaf3cb-49c6-4c0c-8add-27254c07fd9e

The open-access MAF lists 106 somatic variants for this specimen: 68 protein-altering or splice-affecting, 38 silent.
By variant classification: Missense Mutation 58, Silent 38, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | hotspot (GDC flag); catalogued as CM994441, COSV57323819; called by muse, mutect2, varscan2
- TP53 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; called by muse, mutect2, varscan2
- ABRAXAS1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748680448, COSV100426792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs746976575, COSV54266306; called by muse, mutect2, varscan2
- ADGRB1 | c.1559C>A p.P520Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60095908; called by mutect2, varscan2
- ALG13 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV52638348; called by muse, mutect2, varscan2
- ATP1A1 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV55191009; called by muse, mutect2, varscan2
- ATP2B3 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs782210278, COSV54845726, COSV54863591; called by muse, mutect2, varscan2
- BCKDHB | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs755159101, COSV57512539; called by muse, mutect2, varscan2
- BRWD3 | c.985+2T>C p.X329_splice | Splice Site (SNP) | VAF 47/92 reads (51%) | catalogued as COSV64747444; called by mutect2, varscan2
- CBR4 | c.275T>C p.L92S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60370087; called by muse, mutect2, varscan2
- CCDC191 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.167); catalogued as COSV55671863; called by mutect2, varscan2
- CFAP54 | c.6683T>G p.V2228G | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100733095; called by muse, mutect2
- CRMP1 | c.1627+1G>A p.X543_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV61479898; called by muse, mutect2, varscan2
- CXCR1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs140803476; called by muse, mutect2, varscan2
- DDX58 | c.2189G>C p.R730T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65883047; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2
- DSPP | c.1981A>G p.N661D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs866764645; called by muse, mutect2
- EPHA3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100348358; called by muse, mutect2
- EXPH5 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV56201674; called by muse, mutect2, varscan2
- FAM174A | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV57062837; called by muse, mutect2
- FAT4 | c.14401C>T p.R4801C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199895179, COSV58671338; called by muse, mutect2
- FNDC3A | c.2122G>T p.E708* (on ENST00000492622 / NM_001079673.2; = p.E652* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV68132949; called by muse, mutect2, varscan2
- GAMT | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52038658; called by muse, mutect2, varscan2
- GJA5 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as rs372883419; called by muse, mutect2, varscan2
- GPR3 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs773839923, COSV64994650, COSV64995260; called by muse, mutect2, varscan2
- GRIK2 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV59732401; called by muse, mutect2, varscan2
- HOOK3 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56881991; called by muse, mutect2, varscan2
- HPGD | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV56662593; called by muse, mutect2, varscan2
- HUS1B | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV57864447; called by muse, mutect2, varscan2
- INPP4A | c.1981G>A p.A661T (on ENST00000074304 / NM_001134224.1; = p.A622T on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50790536; called by muse, mutect2, varscan2
- ITPRID1 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as COSV60073671; called by muse, mutect2
- KCNE1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs150454912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRA5 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs146444616; called by muse, mutect2, varscan2
- MAP4K3 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55712538; called by muse, mutect2, varscan2
- MEPE | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs138152179, COSV100734898; called by muse, mutect2, varscan2
- MPZ | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100337850; called by muse, mutect2, varscan2
- MSH2 | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1553353246, COSV99253676; ClinVar: uncertain significance; called by muse, mutect2
- NDUFA9 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767462328, COSV56928950; called by muse, mutect2, varscan2
- NOS1AP | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62634401; called by muse, mutect2, varscan2
- NR2C1 | c.432T>A p.N144K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV58008931; called by muse, mutect2, varscan2
- OLFM1 | c.1399G>A p.G467S (on ENST00000371793 / NM_001282611.2; = p.G449S on NM_014279.5) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs774962345, COSV53278064; called by muse, mutect2, varscan2
- OR4D11 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs111401744; called by muse, mutect2, varscan2
- PAM | c.2804G>A p.R935Q (on ENST00000438793 / NM_001319943.1; = p.R936Q on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773572053, COSV99173280; called by mutect2, varscan2
- PCDH1 | c.1272G>C p.E424D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV99745981; called by muse, mutect2
- PDCD11 | c.4375C>T p.Q1459* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as COSV63933829; called by muse, mutect2, varscan2
- RBM17 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); catalogued as COSV65913915; called by muse, mutect2, varscan2
- RCOR2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353238538, COSV100036159; called by muse, mutect2
- RGS22 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62661124; called by muse, mutect2, varscan2
- RUNX1T1 | c.1441A>G p.T481A (on ENST00000265814 / NM_001198628.1; = p.T454A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56145156; called by muse, mutect2, varscan2
- RXFP3 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.013); catalogued as COSV57504671; called by muse, mutect2, varscan2
- SEZ6 | c.2513G>T p.C838F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57979427; called by muse, mutect2, varscan2
- SPART | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV62085094; called by muse, mutect2
- SPC25 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV56371028; called by muse, mutect2
- SPTA1 | c.5903C>A p.A1968E | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV63752366, COSV63757063; called by muse, mutect2, varscan2
- TAF1L | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1321541962, COSV54258116; called by muse, mutect2, varscan2
- TAF3 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1024351500, COSV60203555; called by muse, mutect2, varscan2
- TARBP2 | c.556C>A p.P186T (on ENST00000266987 / NM_134323.2; = p.P165T on NM_004178.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99908459, COSV99908474; called by muse, mutect2
- TMCC3 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as COSV54153979, COSV99705310; called by muse, mutect2, varscan2
- UXS1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51677023; called by muse, mutect2, varscan2
- XIRP2 | c.5680A>G p.T1894A (on ENST00000628543; = p.T2069A on NM_152381.6) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1022412272, COSV99741656; called by muse, mutect2
- ZIM2 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV55632048; called by muse, mutect2, varscan2
- ZNF274 | c.1591G>A p.G531R (on ENST00000610905; = p.G426R on NM_016324.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58763580; called by muse, mutect2, varscan2
- ZNF334 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1364509012, COSV61618421; called by muse, mutect2
- ZNF484 | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60259164; called by muse, mutect2
- IFT80 | c.2049_2053del p.V685Sfs*8 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | called by mutect2, pindel, varscan2
- PI4KB | c.81del p.S28Pfs*3 (on ENST00000368873 / NM_001369623.1; = p.S40Pfs*3 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS7 | c.195C>T p.R65= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV66307012; called by muse, mutect2, varscan2
- AGAP3 | c.744G>A p.K248= (on ENST00000622464; = p.K284= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs760791916, COSV58994406; called by muse, mutect2, varscan2
- ASMT | c.729G>A p.P243= (on ENST00000381229; = p.P271= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/230 reads (35%) | catalogued as rs756221219, COSV67109590; called by muse, mutect2, varscan2
- ATG2A | c.4128T>C p.D1376= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101034203; called by mutect2, varscan2
- CDH1 | c.2184G>A p.L728= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV55731790; called by muse, mutect2, varscan2
- CDH1 | c.2185C>T p.L729= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV55731802; called by muse, mutect2, varscan2
- DDIAS | c.129A>G p.K43= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs561386530, COSV100231149; called by muse, mutect2, varscan2
- DLGAP5 | c.1884C>T p.V628= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV55963073; called by muse, mutect2, varscan2
- FSIP2 | c.19476C>A p.A6492= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV58084370; called by muse, mutect2, varscan2
- IGBP1 | c.735C>T p.L245= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60556126; called by muse, mutect2, varscan2
- IMPA2 | c.762C>T p.L254= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1232736356, COSV52318906, COSV52320164; called by muse, mutect2, varscan2
- IRF4 | c.468G>A p.T156= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs765193356, COSV66705102; called by mutect2, varscan2
- JAKMIP1 | c.1542C>T p.D514= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs140800814; called by muse, mutect2, varscan2
- L1CAM | c.3198G>A p.Q1066= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100649044; called by muse, mutect2
- LARP1 | c.2571T>C p.P857= (on ENST00000518297 / NM_033551.3; = p.P780= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs960213079, COSV60426593; called by muse, mutect2, varscan2
- MASP1 | c.1287A>G p.L429= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99397071; called by muse, mutect2, varscan2
- MROH2B | c.4083C>T p.V1361= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs779752867, COSV68182909; called by muse, mutect2, varscan2
- MTMR9 | c.1512C>A p.S504= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV55312152; called by muse, mutect2, varscan2
- OSMR | c.741C>T p.T247= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs138387186, COSV57093155; called by muse, mutect2, varscan2
- PAK4 | c.1668C>T p.D556= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV58944842; called by muse, mutect2
- PCDHB13 | c.1683G>A p.V561= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99507134; called by muse, mutect2, varscan2
- PLEC | c.237C>T p.I79= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs782255533, COSV59628269; called by muse, mutect2
- PLEKHA4 | c.69C>T p.S23= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1305041605, COSV99565981; called by muse, mutect2
- PLXNA1 | c.606C>A p.S202= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV52525550; called by muse, mutect2, varscan2
- RDX | c.933G>A p.E311= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV58193183; called by muse, mutect2, varscan2
- RTN4RL1 | c.972C>T p.A324= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs200787705, COSV58675493; called by muse, mutect2, varscan2
- SAFB2 | c.381C>T p.G127= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99385643; called by muse, mutect2, varscan2
- SIM1 | c.897G>A p.A299= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1272029649, COSV53491584; called by muse, mutect2, varscan2
- SLC16A9 | c.18G>A p.S6= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs370558954; called by mutect2, varscan2
- SLC30A2 | c.243C>T p.C81= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV65332645; called by muse, mutect2, varscan2
- ST8SIA3 | c.507G>A p.G169= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs905465848, COSV60653621, COSV60654042; called by muse, mutect2, varscan2
- TAF9 | c.234C>T p.R78= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as rs139330602; called by muse, mutect2, varscan2
- TECPR2 | c.3126G>A p.T1042= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs200175137, COSV63973740; called by muse, mutect2, varscan2
- THBS2 | c.2712C>T p.G904= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs771072660, COSV64678578; called by mutect2, varscan2
- TRPS1 | c.2484G>A p.R828= (on ENST00000220888 / NM_001330599.2; = p.R841= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV55238153; called by muse, mutect2, varscan2
- TTN | c.88707A>G p.Q29569= (on ENST00000591111; = p.Q22145= on NM_003319.4) | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100606264; called by muse, mutect2
- UBE4B | c.1710G>C p.R570= (on ENST00000343090 / NM_001105562.3; = p.R441= on NM_006048.5) | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV53531633; called by muse, mutect2
- ZNF276 | c.942C>T p.S314= (on ENST00000443381 / NM_001113525.2; = p.S239= on NM_152287.4) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs555344793, COSV57067859; called by muse, mutect2, varscan2
